Somatic mutation profile of cancer-model specimen HCM-CSHL-0659-C18-85N (3D Organoid, passage 6; aliquot HCM-CSHL-0659-C18-85N-01D-A85C-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0659-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.9 years (17,861 days).
Specimen HCM-CSHL-0659-C18-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 416489f3-7ee0-4fe2-b6a5-71939e2a1689.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0659-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0659-C18-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12153a71-c2d1-4b64-b3de-a428441c672f

The open-access MAF lists 113 somatic variants for this specimen: 80 protein-altering or splice-affecting, 28 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 28, Nonsense Mutation 5, Frame Shift Del 4, Intron 3, Splice Region 2, Splice Site 1, 3'UTR 1, Nonstop Mutation 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 123/246 reads (50%) | catalogued as rs137854573, CM920034, COSV57321615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 200/413 reads (48%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 316/316 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 334/334 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM30 | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 106/432 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368574621; called by muse, varscan2
- BHLHE41 | c.877_899del p.P293Gfs*199 | Frame Shift Del (DEL) | VAF 206/387 reads (53%) | catalogued as rs775321769; called by mutect2, varscan2
- BTK | c.1176C>T p.Y392= | Splice Region (SNP) | VAF 127/340 reads (37%) | catalogued as rs782429199, CM015165; called by muse, mutect2, varscan2
- CARD10 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 214/515 reads (42%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.996); catalogued as rs1219933095; called by muse, mutect2, varscan2
- CD58 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 243/543 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as rs868654964; called by muse, mutect2, varscan2
- CDC37 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 328/672 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs111718868; called by muse, varscan2
- CHAF1A | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 229/422 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs61729782, COSV56671678, COSV56675931; called by muse, varscan2
- COL4A2 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 246/1500 reads (16%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.023); catalogued as rs1189428009; called by muse, mutect2, varscan2
- CSMD3 | c.8677T>G p.F2893V (on ENST00000297405 / NM_001363185.1; = p.F2724V on NM_052900.3) | Missense Mutation (SNP) | VAF 162/753 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as COSV52338035; called by muse, mutect2, varscan2
- CUX2 | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 136/309 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376543487; called by muse, mutect2, varscan2
- CXXC1 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 204/205 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.84); catalogued as rs777125163; called by muse, mutect2, varscan2
- CYP11A1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 155/307 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs781754675, COSV51430446; called by muse, varscan2
- EXO1 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 240/504 reads (48%) | catalogued as rs560322680, COSV62216380, COSV62218435; called by muse, mutect2, varscan2
- FCN3 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs757913198, COSV54642815; called by muse, mutect2
- HOGA1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 208/465 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs541591157; called by muse, mutect2
- HYDIN | c.7574G>A p.R2525H | Missense Mutation (SNP) | VAF 322/672 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756437118, COSV59262649; called by muse, varscan2
- IL1RAPL2 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 183/375 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375566296, COSV100781898; called by muse, varscan2
- KBTBD4 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 210/453 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1297690080; called by muse, varscan2
- KCNH4 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 230/489 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.152); catalogued as rs779078549, COSV52920690; called by muse, mutect2, varscan2
- KDR | c.2413G>A p.V805I | Missense Mutation (SNP) | VAF 192/399 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs149212892, COSV99028755; called by muse, varscan2
- KIF16B | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 122/122 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs752942736, COSV61706691; called by muse, varscan2
- KIT | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 248/504 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs557317141, COSV99078452; ClinVar: uncertain significance; called by muse, varscan2
- LHX4 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 185/350 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs749318884, CM128531; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1B | c.2623G>A p.D875N | Missense Mutation (SNP) | VAF 113/239 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs768074082, COSV63341619, COSV63342088; called by muse, mutect2, varscan2
- LRRK1 | c.2521C>T p.R841W | Missense Mutation (SNP) | VAF 145/151 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375374079; called by muse, mutect2, varscan2
- MAGI2 | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 165/302 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs751367419, COSV100833490; called by muse, varscan2
- MARCHF7 | c.1501A>G p.M501V | Missense Mutation (SNP) | VAF 169/366 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs375480374; called by muse, varscan2
- MMP12 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 130/300 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs200973192, COSV100404873; called by muse, varscan2
- MYOM2 | c.4028G>A p.R1343H | Missense Mutation (SNP) | VAF 220/220 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs774701653, COSV50703881; called by muse, varscan2
- NLRP1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 413/414 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs200691997, COSV52562503; called by muse, varscan2
- OR5L2 | c.32A>C p.E11A | Missense Mutation (SNP) | VAF 191/415 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV65723460, COSV65724594, COSV65724996; called by muse, varscan2
- PCLO | c.9881A>C p.E3294A | Missense Mutation (SNP) | VAF 169/464 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV61654928; called by muse, mutect2, varscan2
- RGPD4 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 265/510 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61747829; called by muse, mutect2, varscan2
- RGS22 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 127/511 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs753306452; called by muse, mutect2, varscan2
- RPH3A | c.2084A>G p.*695Wext*18 (on ENST00000389385 / NM_001143854.2; = p.*691Wext*18 on NM_014954.4 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 133/251 reads (53%) | catalogued as rs1304421730; called by muse, mutect2, varscan2
- SDCBP2 | c.563C>T p.P188L (on ENST00000339987 / NM_001199784.1; = p.P103L on NM_015685.5) | Missense Mutation (SNP) | VAF 162/164 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1401197027, COSV60590753; called by muse, varscan2
- SEPTIN1 | c.579G>A p.R193= (on ENST00000321367; = p.R146= on NM_052838.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 134/280 reads (48%) | catalogued as COSV58442593; called by muse, varscan2
- SNTG2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 530/530 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as rs201970591; called by muse, mutect2, varscan2
- TANC2 | c.2558C>T p.A853V | Missense Mutation (SNP) | VAF 147/357 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV67332340; called by muse, mutect2, varscan2
- TMCO4 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 274/558 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs943688187; called by muse, varscan2
- TMEM104 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 278/559 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.303); catalogued as rs770423788; called by muse, mutect2, varscan2
- TRGV10 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 156/394 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs1045663060; called by muse, varscan2
- TRPM2 | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 151/346 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs141768349; called by muse, mutect2, varscan2
- ZNF609 | c.4021G>A p.V1341I | Missense Mutation (SNP) | VAF 266/524 reads (51%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs373171885; called by muse, mutect2, varscan2
- ZNF813 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 151/323 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV67175550; called by muse, mutect2, varscan2
- ABCA10 | c.965_967del p.F322del | In Frame Del (DEL) | VAF 87/211 reads (41%) | called by mutect2, pindel, varscan2
- ADGRA3 | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 23/308 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- APLP1 | c.693G>A p.W231* | Nonsense Mutation (SNP) | VAF 50/415 reads (12%) | called by muse, mutect2, varscan2
- ATL3 | c.1213G>A p.G405S | Missense Mutation (SNP) | VAF 203/438 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- BOD1L1 | c.8749+1G>A p.X2917_splice | Splice Site (SNP) | VAF 136/291 reads (47%) | called by muse, varscan2
- CANX | c.1760_1761del p.R587Kfs*10 | Frame Shift Del (DEL) | VAF 117/319 reads (37%) | called by mutect2, pindel, varscan2
- CDH8 | c.1314G>T p.Q438H | Missense Mutation (SNP) | VAF 155/347 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CISD1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 181/359 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- E2F3 | c.198del p.T67Pfs*13 | Frame Shift Del (DEL) | VAF 377/978 reads (39%) | called by pindel, varscan2
- FAT3 | c.7623G>T p.K2541N | Missense Mutation (SNP) | VAF 161/378 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FNDC1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 132/365 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FREM1 | c.4390A>G p.T1464A | Missense Mutation (SNP) | VAF 380/382 reads (99%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, varscan2
- GCC2 | c.2088A>C p.K696N | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- GRK7 | c.1198A>G p.K400E | Missense Mutation (SNP) | VAF 172/667 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HSPA9 | c.253A>T p.R85* | Nonsense Mutation (SNP) | VAF 184/377 reads (49%) | called by muse, mutect2, varscan2
- IGSF10 | c.7537G>A p.G2513S | Missense Mutation (SNP) | VAF 225/763 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL9R | c.135A>C p.E45D | Missense Mutation (SNP) | VAF 184/430 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by mutect2, varscan2
- MAGI1 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 129/215 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC4 | c.5419A>T p.I1807F | Missense Mutation (SNP) | VAF 388/2003 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); called by muse, mutect2
- NCOA1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 281/281 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PRDM2 | c.5125G>C p.A1709P | Missense Mutation (SNP) | VAF 193/381 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRR32 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 296/665 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RAB26 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 28/514 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by muse, mutect2
- RFX5 | c.533T>G p.L178R | Missense Mutation (SNP) | VAF 87/227 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF130 | c.799T>A p.C267S | Missense Mutation (SNP) | VAF 172/366 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF17 | c.355del p.D119Ifs*3 | Frame Shift Del (DEL) | VAF 60/660 reads (9%) | called by mutect2, pindel
- SERPINE2 | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 142/303 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- SPACA9 | c.25C>A p.R9S | Missense Mutation (SNP) | VAF 44/395 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- ST6GAL2 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 210/450 reads (47%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMPRSS11D | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 146/356 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.334); called by mutect2, varscan2
- WDFY4 | c.4603G>T p.A1535S | Missense Mutation (SNP) | VAF 228/498 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AFMID | c.528C>T p.A176= | Silent (SNP) | VAF 201/429 reads (47%) | catalogued as rs762142448; called by muse, varscan2
- BEX4 | c.63C>T p.N21= | Silent (SNP) | VAF 166/327 reads (51%) | called by muse, varscan2
- CHD9 | c.5904G>A p.R1968= | Silent (SNP) | VAF 207/417 reads (50%) | called by muse, mutect2, varscan2
- CYP2A6 | c.171C>T p.S57= | Silent (SNP) | VAF 134/453 reads (30%) | called by muse, mutect2, varscan2
- DNAH17 | c.2628G>A p.Q876= | Silent (SNP) | VAF 174/333 reads (52%) | called by muse, mutect2, varscan2
- DOCK4 | c.2181C>T p.N727= | Silent (SNP) | VAF 331/560 reads (59%) | catalogued as rs190956823; called by muse, mutect2, varscan2
- EDC4 | c.582C>T p.C194= | Silent (SNP) | VAF 179/423 reads (42%) | catalogued as rs745537523; called by muse, varscan2
- FBXO46 | c.1362C>T p.H454= | Silent (SNP) | VAF 141/666 reads (21%) | called by muse, mutect2, varscan2
- FOXN4 | c.705C>T p.D235= | Silent (SNP) | VAF 178/403 reads (44%) | catalogued as rs762252668; called by muse, mutect2, varscan2
- LRP1 | c.10185C>T p.G3395= | Silent (SNP) | VAF 222/449 reads (49%) | catalogued as rs762075951; called by muse, mutect2, varscan2
- MEN1 | c.1185G>A p.P395= | Silent (SNP) | VAF 194/434 reads (45%) | catalogued as rs587780841; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- MIB2 | c.723C>T p.L241= | Silent (SNP) | VAF 278/566 reads (49%) | catalogued as rs374072350; called by muse, varscan2
- NR1I3 | c.510G>A p.L170= | Silent (SNP) | VAF 181/382 reads (47%) | called by muse, varscan2
- NYAP1 | c.1482C>T p.V494= | Silent (SNP) | VAF 262/709 reads (37%) | called by muse, mutect2, varscan2
- OR10D3 | c.297C>T p.C99= | Silent (SNP) | VAF 192/392 reads (49%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1899C>T p.D633= | Silent (SNP) | VAF 460/928 reads (50%) | catalogued as COSV52025688; called by muse, mutect2, varscan2
- PDZD4 | c.1338C>T p.S446= | Silent (SNP) | VAF 332/682 reads (49%) | catalogued as rs782509412; called by muse, varscan2
- PER3 | c.60C>T p.G20= | Silent (SNP) | VAF 242/513 reads (47%) | catalogued as rs773148390; called by muse, varscan2
- PLG | c.876C>T p.S292= | Silent (SNP) | VAF 347/569 reads (61%) | catalogued as rs753737813, COSV51983450; called by muse, mutect2, varscan2
- PPP2R1A | c.360G>A p.S120= | Silent (SNP) | VAF 236/510 reads (46%) | catalogued as rs11537700, COSV59045417; called by muse, varscan2
- PPP2R2D | c.687G>A p.E229= | Silent (SNP) | VAF 195/415 reads (47%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2403G>A p.G801= | Silent (SNP) | VAF 336/733 reads (46%) | catalogued as rs1395944511; called by muse, mutect2, varscan2
- SP110 | c.1830T>A p.G610= | Silent (SNP) | VAF 152/318 reads (48%) | called by muse, varscan2
- STAG3 | c.1329C>A p.A443= | Silent (SNP) | VAF 22/528 reads (4%) | called by muse, mutect2
- TECTB | c.9G>A p.T3= | Silent (SNP) | VAF 183/426 reads (43%) | catalogued as rs139784993; called by muse, mutect2, varscan2
- TMC2 | c.2037C>T p.N679= | Silent (SNP) | VAF 264/264 reads (100%) | catalogued as rs759453479, COSV62657998; called by muse, mutect2, varscan2
- TMEM132C | c.99C>T p.H33= | Silent (SNP) | VAF 105/242 reads (43%) | catalogued as rs1215663899; called by muse, varscan2
- ZSCAN10 | c.2163C>T p.R721= (on ENST00000252463; = p.R776= on NM_032805.3) | Silent (SNP) | VAF 261/574 reads (45%) | catalogued as rs1463274360; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825157 A>C | 5'Flank (SNP) | VAF 20/358 reads (6%) | called by muse, mutect2
- KCTD1 | c.-15-46075G>A | Intron (SNP) | VAF 157/158 reads (99%) | catalogued as rs1567988850; called by muse, varscan2
- MPPED2 | c.*2160C>A | 3'UTR (SNP) | VAF 143/336 reads (43%) | called by muse, mutect2, varscan2
- MYH14 | c.1922-1992C>G | Intron (SNP) | VAF 127/282 reads (45%) | catalogued as COSV51828646; called by muse, mutect2, varscan2
- ZNF829 | c.-85+123G>A | Intron (SNP) | VAF 248/510 reads (49%) | called by muse, varscan2
